CCDI case PBBYMD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/75a49b03-cc70-4e66-a3ca-c669294c0bb1

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.0 years (5,854 days).

Biospecimens (3 samples)
- Sample 0DKRCE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKRCQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKRD3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
